MP2PRT case MP2PRT-PAUUFW — Molecular Profiling to Predict Response to Treatment - Wilms Tumor (MP2PRT-WT)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Kidney.
https://portal.gdc.cancer.gov/cases/dbd6bf13-ca85-424a-a8f2-0ed96ee2d360

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 2011; Vital status: Alive.

Diagnoses (1)
1. Nephroblastoma, NOS: ICD-O-3 morphology code: 8960/3; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Age at diagnosis: 0.7 years (270 days); Wilms tumor histologic subtype: Favorable.
   Treatment — whether it was given is not recorded by GDC; Regimen or line of therapy: EE-4A.

Biospecimens (3 samples)
- Sample MP2PRT-PAUUFW-NB1-A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
- Sample MP2PRT-PAUUFW-TTM2-A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Biospecimen anatomic site: Abdomen; Preservation method: Cryopreserved.
- Sample MP2PRT-PAUUFW-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Cryopreserved.
